Surgical pathology report (de-identified scan), TCGA case TCGA-2J-AABH, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Mayo Clinic, specimen TCGA-2J-AABH-01A (Primary Tumor).

[page 1 of 2]
Surgery Date:

Surgical Pathology

ICD-O-3

Adenocarcinoma NOS 8140/3
Site: Pancreas body C25.1
J205/5/14

DIAGNOSIS:

A. Pancreas, neck margin, biopsy: Negative for tumor.

B. Pancreas, spleen and omentum, distal pancreatectomy, splenectomy and partial omentectomy: Invasive grade 3 (of 4) adenocarcinoma, forming a 2.2 x 2.0 x 1.8 cm mass within the body of the pancreas. The tumor extends beyond the pancreas to involve peripancreatic soft tissue. Perineural invasion is identified. The pancreatic ducts demonstrate pancreatic intraepithelial neoplasia (PanIN-1A). The distal pancreas shows chronic pancreatitis. The surgical resection margins, including the separately submitted pancreatic neck, are negative for tumor (2.0 cm to pancreatic neck margin). Multiple (6 peripancreatic, 2 omental) lymph nodes are negative for tumor. The spleen parenchyma is unremarkable.

[With available surgical material, AJCC pT3N0 7th edition, 2010.]

This final pathology report is based on the gross/macrosopic examination and frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "pancreatic neck margin - margin up" is a 2.5 x 2.2 x 0.7 cm portion of pancreatic tissue with orientation. Margin submitted. Grossed by

B. Received fresh labeled "distal pancreas, spleen" is a distal pancreatectomy specimen consisting of 10.5 x 3.1 x 1.8 cm portion of pancreas, 140.0 gram, 14.0 x 10.5 x 3.6 cm spleen, and a 13.0 x 9.0 x 3.5 cm omentum. A 2.2 x 2.0 x 1.8 cm white, solid mass is present within the body of the pancreas, 2.0 cm from the proximal pancreatic margin and obstructing the main pancreatic duct. The mass does not grossly appear to be confined to the pancreas. The distal pancreas shows features suggestive of chronic pancreatitis. Peripancreatic and omental lymph nodes are identified. The spleen is grossly unremarkable. Representative sections are submitted. Grossed by

BLOCK SUMMARY:

Part A: Pancreatic neck margin

1 Pancreatic neck margin 1

[page 2 of 2]
2 Pancreatic neck margin 2

Part B: Distal pancreas and spleen

- 1 Pancreatic duct
- 2 Pancreas mass 1
- 3 Pancreas mass 2
- 4 Pancreas
- 5 Spleen
- 6 Peripancreatic LN5(B1)
- 7 Peripancreatic LN2(B2)
- 8 Omental LN2(B4)
- 9 Omental LN3(B5)
- 10 Peripancreatic LN2(B3)

Source: NCI Genomic Data Commons file 457e1ddd-db30-48f5-b0ca-f1cd22689795 (TCGA-2J-AABH.2E34BABE-5262-469C-BFFA-B75A75763381.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).